Surgical pathology report (de-identified scan), TCGA case TCGA-CC-5258, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-5258-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Carcinoma, hepatocellular, NOS 817013

Site: Liver C22.0 1/28/11

ID#:

Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
LIVER TUMOR	4 x 4 x 2 cm		6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: II	
Notes:			
UWID: F63EEB94-37AE-43FC-97B9-8EBF328C2134 TCGA-CC-5258-01A-PR Redacted 			

H/PA Discrepancy		X
Dual/Synchronous Primary, Noted		
R. Reviewer: _____	Date Reviewed: _____	

[page 2 of 2]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			☒	Streaming			
Mosaic		☒		Storiform			
Necrosis		☒		Fibrosis			
Lymphocytic Infiltration		☒	☒	Palisading			
Vascular Invasion		☒	☒	Cystic Degeneration			
Clusterized		☒		Bleeding			
Alveolar Formation			☒	Myxoid Change			
Indian File			☒	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation		☒	Myoblast			Plasma Cell		

Otherwise Specified:

Cancer: D, 50% D2 75%, D3 60% D4 60% Necrosis 10%

2. Cellular Differentiation:

Well	Moderately	Poor
		☒

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				☒
Hyperchromatism			☒	
Nucleolar Prominent				☒
Multinucleated Giant Cell				☒
Mitotic Activity				☒
Nuclear Grade				

Histological Diagnosis: *Hepatocellular Carcinoma G2*

Comments: _____

Date

Signature

Source: NCI Genomic Data Commons file 21c53f43-1e09-4441-bddd-41c384cfd830 (TCGA-CC-5258.F63EEB94-37AE-43FC-97B9-8EBF328C2134.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).